CCDI case PBBTMJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/28f0dcef-3696-4624-8e67-1962f475ca50

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ewing sarcoma: ICD-O-3 morphology code: 9260/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 16.4 years (5,984 days).

Biospecimens (3 samples)
- Sample 0DGWO9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGWOB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGWOG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
